Somatic mutation profile of tumor specimen TCGA-50-8460-01A (aliquot TCGA-50-8460-01A-11D-2323-08) from TCGA case TCGA-50-8460, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 74.7 years (27,270 days).
Specimen TCGA-50-8460-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1875b28-01c3-4271-94ce-23815e4bb1f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-8460-10A (Blood Derived Normal), aliquot TCGA-50-8460-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc9ea226-6b5d-4214-86f6-e8fa3ae7a564

The open-access MAF lists 31 somatic variants for this specimen: 27 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 22, Silent 4, Nonsense Mutation 2, Splice Region 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 5/40 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100856573; called by muse, mutect2, varscan2
- ANKRD12 | c.4237G>A p.V1413M | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.03); catalogued as rs562592238, COSV100040871; called by muse, mutect2, varscan2
- ASXL1 | c.3433G>T p.G1145C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.914); catalogued as COSV100037997; called by muse, mutect2, varscan2
- BBS7 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99144828; called by muse, mutect2, varscan2
- BRCA2 | c.2933A>G p.N978S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.167); catalogued as rs775890004, COSV101203990, COSV66462066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C12orf42 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV100171860; called by muse, mutect2, varscan2
- CACTIN | c.2188T>A p.Y730N | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99698338; called by mutect2, varscan2
- COL25A1 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | catalogued as COSV101211258; called by muse, mutect2, varscan2
- DNAAF5 | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as rs751454661, COSV52418008; called by muse, mutect2, varscan2
- GAP43 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100525355; called by muse, mutect2, varscan2
- IGKV3-20 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs548180684; called by muse, mutect2, varscan2
- LDHC | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs771264967, COSV99772303; called by muse, mutect2, varscan2
- LRRC17 | c.930C>A p.A310= | Splice Region (SNP) | VAF 9/104 reads (9%) | catalogued as COSV50870386; called by muse, mutect2
- MAP3K19 | c.2362T>G p.L788V | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV100209598; called by muse, mutect2
- MC4R | c.41A>C p.H14P | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100235881; called by muse, mutect2, varscan2
- MRPS35 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99317324, COSV99317505; called by muse, mutect2
- NAV1 | c.2195A>G p.N732S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV99818333; called by muse, mutect2, varscan2
- OR10H4 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs140667599; called by muse, mutect2, varscan2
- PCDHA6 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.364); catalogued as COSV101131218; called by muse, mutect2, varscan2
- PDXK | c.200A>C p.E67A | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV99376133; called by muse, mutect2, varscan2
- RGS18 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100817675; called by muse, mutect2, varscan2
- SLC15A3 | c.1517G>A p.G506D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99134170; called by muse, mutect2
- TCL1B | c.174C>A p.S58R | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100525719; called by muse, mutect2, varscan2
- TXNRD1 | c.1756G>A p.V586M (on ENST00000525566 / NM_001093771.3; = p.V488M on NM_003330.4) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100723334; called by muse, mutect2
- OR1L6 | c.642_644dup p.F215dup (on ENST00000373684; = p.F179dup on NM_001004453.2) | In Frame Ins (INS) | VAF 19/124 reads (15%) | called by mutect2, varscan2
- ZCRB1 | c.282_283insCAGCTAAG p.F95Qfs*25 | Frame Shift Ins (INS) | VAF 13/57 reads (23%) | called by mutect2, varscan2
- LPCAT2 | c.520C>T p.L174= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as rs1567393819, COSV50898081; called by muse, mutect2, varscan2
- RIPK1 | c.1596C>T p.T532= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99454098; called by muse, mutect2, varscan2
- RPL10L | c.204C>G p.A68= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV100022418; called by muse, mutect2, varscan2
- ZIC1 | c.543G>T p.V181= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs769657730, COSV99291602; called by muse, mutect2, varscan2
